Gene-level copy-number profile of tumor specimen TCGA-02-2486-01A from TCGA case TCGA-02-2486, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.0 years (23,394 days).
Specimen TCGA-02-2486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.74715f2b-fabc-4b3a-9819-aae6dcde8d3c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-2486-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9e3a7f6-2241-4d33-8afe-3f27d5cb646d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 12,060; copy number 2: 44,679; copy number 3: 3,004; copy number 5: 25; copy number 15: 1; copy number 17: 1; copy number 32: 4; copy number 36: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-02-2486-01A-01D-0784-01): tumor purity 0.72, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,227,243–22,128,103, 39 genes: IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,621,025–55,260,256, 12 genes, copy number 15–36 (within-gene range 11–36): RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:141,074,064–141,841,487, 25 genes, copy number 5 (within-gene range 3–5): TMEM178B, AC006362.1, NDUFB10P2, AC005692.3, AC005692.1, AC005692.2, AC073878.1, AC073878.2, AGK, AC004918.1, DENND11, AC004918.3, WEE2-AS1, WEE2, RNU1-82P, SSBP1, TAS2R3, TAS2R4, TAS2R6P, TAS2R5, MTCO1P55, MTND2P5, MTND1P3, MYL6P4, PRSS37.

Autosomal genes at a single copy (total copy number 1): 9,673. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
